Somatic mutation profile of tumor specimen 0DRSU0 from CCDI case PBCHBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.6 years (967 days).
Specimen 0DRSU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfa8cb20-8b5c-416d-b953-74ef79d05e67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRSSD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/980aead7-1327-4d72-81de-439c00107d22

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN6 | c.2731G>T p.A911S | Missense Mutation (SNP) | VAF 51/411 reads (12%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.985); catalogued as COSV100611561; called by muse, mutect2, varscan2
- CSPG4 | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753948018; called by muse, mutect2, varscan2
- ISLR2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1245525710; called by muse, mutect2
- CELSR1 | c.7378C>A p.R2460S | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM120C | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 70/438 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- LHX6 | c.981C>T p.C327= (on ENST00000373755 / NM_001242334.2; = p.C356= on NM_014368.5) | Silent (SNP) | VAF 35/223 reads (16%) | catalogued as rs202183953, COSV61344225; called by muse, mutect2, varscan2
- CDC42EP2 | c.-91C>T | 5'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as rs376544371; called by muse, mutect2
